Somatic mutation profile of tumor specimen TCGA-94-A5I6-01A (aliquot TCGA-94-A5I6-01A-21D-A27K-08) from TCGA case TCGA-94-A5I6, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.8 years (22,949 days).
Specimen TCGA-94-A5I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99da6e3d-4d29-4060-8878-92e1d8ba559e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-94-A5I6-10A (Blood Derived Normal), aliquot TCGA-94-A5I6-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee9076ad-1b57-41d5-bd65-9d82bb6c173a

The open-access MAF lists 179 somatic variants for this specimen: 139 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 36, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 3, RNA 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 24/51 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 20/82 reads (24%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99367859; called by muse, mutect2, varscan2
- AC098582.1 | c.2485A>T p.S829C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99985615; called by muse, mutect2, varscan2
- ADAM33 | c.2050G>T p.G684C | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768266697, COSV100597887; called by muse, mutect2, varscan2
- ADD2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as COSV100035677; called by muse, mutect2, varscan2
- ANKFN1 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs769090545, COSV100593506; called by muse, mutect2, varscan2
- ANKS1B | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100245673; called by muse, mutect2, varscan2
- ARFGEF1 | c.1303A>G p.M435V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as rs779019298, COSV99142431; called by mutect2, varscan2
- ARHGEF10 | c.966G>C p.M322I (on ENST00000398564; = p.M297I on NM_014629.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.23); catalogued as COSV100034559; called by muse, mutect2, varscan2
- ATIC | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1281721280, COSV99377809; called by muse, mutect2, varscan2
- ATP10D | c.3706G>T p.A1236S | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.099); catalogued as COSV99905620, COSV99906187; called by muse, mutect2, varscan2
- ATP6V1H | c.1078A>C p.K360Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100778644; called by muse, mutect2, varscan2
- AVIL | c.2054G>A p.G685D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV99142388; called by muse, mutect2
- BACH2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs142517589; called by muse, mutect2, varscan2
- CAPRIN1 | c.2074G>T p.G692W | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100403905; called by muse, mutect2, varscan2
- CC2D1A | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100528485; called by muse, mutect2, varscan2
- CDH10 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.098); catalogued as rs544297913, COSV52569597; called by muse, mutect2, varscan2
- CDH11 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as COSV99218473; called by muse, mutect2, varscan2
- CDH22 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV64836451, COSV64837465; called by muse, mutect2, varscan2
- CDH7 | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100542404; called by muse, mutect2, varscan2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CDNF | c.546C>A p.H182Q | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs757383518, COSV101012372; called by muse, mutect2, varscan2
- CLPB | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV53627600; called by muse, mutect2
- CMYA5 | c.5048A>G p.E1683G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV101484055; called by muse, mutect2, varscan2
- CNKSR2 | c.3032G>T p.S1011I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV101069923; called by muse, mutect2, varscan2
- CNTNAP4 | c.3176G>T p.S1059I | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100271532, COSV56701672; called by muse, mutect2, varscan2
- COL1A1 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV99867258; called by muse, varscan2
- CTNNA2 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100784253, COSV63568291; called by muse, mutect2, varscan2
- DDIAS | c.1931G>C p.R644T | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100231206; called by muse, mutect2, varscan2
- DEFB110 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as COSV101182485; called by muse, mutect2, varscan2
- DIAPH1 | c.3656G>T p.R1219L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53889164, COSV99526619; called by muse, mutect2, varscan2
- DNAH9 | c.9857G>C p.R3286P | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52338512, COSV52370122, COSV99305932; called by muse, mutect2, varscan2
- DNAJC14 | c.807T>A p.C269* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100423603; called by muse, mutect2, varscan2
- DPP6 | c.2058G>C p.K686N (on ENST00000377770 / NM_001364500.2; = p.K624N on NM_001936.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100125709; called by muse, mutect2, varscan2
- EPHA5 | c.2515A>G p.K839E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56678458; called by muse, mutect2, varscan2
- FAT1 | c.7693T>G p.S2565A | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101499356; called by muse, mutect2, varscan2
- FAT2 | c.12785G>T p.R4262L | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV99942932; called by muse, mutect2, varscan2
- FLG2 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 80/484 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV101165883; called by muse, mutect2, varscan2
- FNDC7 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99601275; called by muse, mutect2
- FOLH1 | c.1141T>A p.W381R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99923230; called by muse, mutect2, varscan2
- GLB1L | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs758098195, COSV99850558; called by muse, mutect2, varscan2
- GLMN | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100950055; called by muse, mutect2
- GPIHBP1 | c.500C>A p.A167D | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100427368; called by muse, mutect2, varscan2
- GPR6 | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99254348; called by muse, mutect2, varscan2
- GUCY1A1 | c.1348A>T p.T450S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99637801; called by muse, mutect2, varscan2
- GUCY2F | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99485020; called by muse, mutect2, varscan2
- HAVCR2 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100324764; called by muse, mutect2, varscan2
- HBG2 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV100400638; called by muse, mutect2, varscan2
- HNRNPH1 | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV100270640; called by muse, mutect2, varscan2
- IGFALS | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV99236527; called by muse, mutect2, varscan2
- IL1R1 | c.1067A>G p.Y356C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as COSV99292631; called by muse, mutect2, varscan2
- ITIH4 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99819413; called by muse, mutect2, varscan2
- KCTD16 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV101568811; called by muse, mutect2, varscan2
- KIR3DL3 | c.1125C>A p.D375E | Missense Mutation (SNP) | VAF 101/509 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.273); catalogued as COSV99399919; called by muse, mutect2, varscan2
- KLRC3 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV101122909; called by muse, mutect2, varscan2
- LCE3D | c.70A>C p.K24Q | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.824); catalogued as COSV100909840; called by muse, mutect2, varscan2
- LMO7 | c.251+2T>G p.X84_splice (on ENST00000357063; = p.X99_splice on NM_005358.5) | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as rs1196440457, COSV100442743; called by muse, mutect2, varscan2
- MAEL | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV63304696; called by muse, mutect2, varscan2
- MAGEB6B | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69689822; called by muse, mutect2, varscan2
- MAPK14 | c.682+1G>A p.X228_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100004931; called by muse, mutect2, varscan2
- MED25 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV57203558; called by muse, mutect2, varscan2
- MLLT1 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.037); catalogued as COSV99398035; called by muse, mutect2
- MMP16 | c.1049T>C p.L350P | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99688327; called by muse, mutect2, varscan2
- MORC3 | c.1981G>T p.V661L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs770659896, COSV101264928; called by muse, mutect2, varscan2
- MUC16 | c.26546A>T p.K8849I | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV101199989; called by muse, mutect2, varscan2
- MYBL2 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 73/330 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV53834182, COSV99406348; called by muse, mutect2, varscan2
- MYH1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1432611647, COSV56848015; called by muse, mutect2, varscan2
- MYL12A | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99470173; called by muse, mutect2, varscan2
- MYLK | c.5450A>G p.D1817G | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659108; called by muse, mutect2
- MYO18B | c.6344C>A p.S2115Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100123719, COSV59143903; called by muse, mutect2, varscan2
- NAT2 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99673957, COSV99674083; called by muse, mutect2, varscan2
- NEGR1 | c.639T>A p.D213E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100163625; called by muse, mutect2, varscan2
- NLRP7 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60178833; called by muse, mutect2, varscan2
- NOL4 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); catalogued as COSV99306680; called by muse, mutect2, varscan2
- NPNT | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99975119; called by muse, mutect2, varscan2
- NRSN1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101027271, COSV101027359; called by muse, mutect2, varscan2
- NRXN3 | c.2377G>T p.D793Y (on ENST00000335750 / NM_001330195.2; = p.D420Y on NM_004796.6) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200826, COSV100204075; called by muse, mutect2, varscan2
- NTNG2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs927264414, COSV62365251; called by muse, mutect2
- OR14K1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.088); catalogued as COSV99315212; called by muse, mutect2, varscan2
- OR4K2 | c.895A>T p.R299W | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100064486; called by muse, mutect2, varscan2
- OR52M1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779642009, COSV100798587, COSV64172039; called by muse, mutect2, varscan2
- OR56A4 | c.547C>A p.H183N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as COSV100417544, COSV100417573; called by muse, mutect2
- OR5B2 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100222888; called by muse, mutect2, varscan2
- OR8G5 | c.716G>T p.S239I | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100422430; called by muse, mutect2, varscan2
- PCDH10 | c.2083G>T p.G695W | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.406); catalogued as COSV52087484, COSV99993603; called by muse, mutect2
- PCDHB11 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100697008; called by muse, mutect2, varscan2
- PCDHGB6 | c.1096G>T p.V366F | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99538649; called by muse, mutect2, varscan2
- PCLO | c.9505A>T p.T3169S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV100432966; called by muse, mutect2, varscan2
- PDE8B | c.93C>G p.S31R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.18); catalogued as COSV99366814; called by muse, mutect2
- PKHD1L1 | c.10510C>A p.L3504M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV101006155; called by muse, mutect2, varscan2
- PLEC | c.13096A>G p.I4366V (on ENST00000322810 / NM_201380.4; = p.I4256V on NM_000445.5) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV100514346; called by muse, mutect2, varscan2
- PLEKHG4B | c.685G>A p.E229K (on ENST00000283426; = p.E585K on NM_052909.5) | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.056); catalogued as COSV52049658; called by muse, mutect2, varscan2
- PREX2 | c.2896A>T p.K966* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV99907382; called by muse, mutect2, varscan2
- PRKCB | c.784G>T p.G262W | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV57787563, COSV57793884; called by muse, mutect2, varscan2
- PRKCB | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV57803327; called by muse, mutect2, varscan2
- PRRC1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as COSV99687850; called by muse, mutect2, varscan2
- RAB40AL | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505105; called by muse, mutect2, varscan2
- RABL2B | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100711476; called by muse, mutect2
- RABL2B | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100711477, COSV61483089; called by muse, mutect2
- RAPGEF6 | c.4176A>T p.R1392S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.194); catalogued as COSV99726540; called by muse, mutect2, varscan2
- RARA | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.011); catalogued as COSV99565020; called by muse, mutect2, varscan2
- RECK | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs770475755, COSV100937570, COSV65035464; called by muse, mutect2, varscan2
- RNF17 | c.2848A>T p.I950L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV99693270; called by muse, mutect2, varscan2
- ROBO1 | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458735; called by muse, mutect2, varscan2
- RUBCN | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99583588, COSV99584086; called by muse, mutect2, varscan2
- RUNX1T1 | c.1411G>C p.A471P (on ENST00000265814 / NM_001198628.1; = p.A444P on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56138199, COSV99752138; called by muse, mutect2, varscan2
- SCAF8 | c.3419G>C p.G1140A | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.996); catalogued as COSV100914108; called by muse, mutect2, varscan2
- SEC63 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV100938391; called by muse, mutect2, varscan2
- SLC6A7 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100046296; called by muse, mutect2, varscan2
- SLIT3 | c.2965G>C p.E989Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1410840877, COSV60609738; called by muse, mutect2, varscan2
- SMAD1 | c.1090C>G p.H364D | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV100129747; called by muse, mutect2, varscan2
- SSBP2 | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100283547; called by muse, mutect2, varscan2
- SYNE1 | c.4889C>A p.A1630E (on ENST00000367255 / NM_182961.4; = p.A1637E on NM_033071.3) | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as rs566004273, COSV99564961, COSV99580542; called by muse, mutect2, varscan2
- TGFB1I1 | c.151G>T p.G51* (on ENST00000394863 / NM_001042454.3; = p.G34* on NM_015927.4) | Nonsense Mutation (SNP) | VAF 43/156 reads (28%) | catalogued as COSV100691070; called by muse, mutect2, varscan2
- TMEM120A | c.782T>A p.V261E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100115620; called by muse, varscan2
- TMEM132D | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV101397180, COSV101397913; called by muse, mutect2, varscan2
- TMPRSS15 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99517996; called by muse, mutect2, varscan2
- TNR | c.1355A>C p.K452T | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV99689719; called by muse, mutect2, varscan2
- TRIM58 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV63569668; called by mutect2, varscan2
- TTN | c.27412A>T p.T9138S (on ENST00000591111; = p.T8211S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/102 reads (45%) | PolyPhen benign (0.352); catalogued as COSV100613883; called by muse, mutect2, varscan2
- TTN | c.13463C>A p.T4488K (on ENST00000591111; = p.T3561K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | PolyPhen benign (0.067); catalogued as COSV100613884; called by muse, mutect2, varscan2
- UBTF | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100255956; called by muse, mutect2
- USHBP1 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV99394252; called by muse, mutect2, varscan2
- WDR49 | c.592A>G p.M198V (on ENST00000308378 / NM_001366158.1; = p.M539V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100392825; called by muse, mutect2
- XPNPEP2 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.284); catalogued as COSV100941483; called by muse, mutect2, varscan2
- YY1AP1 | c.1957C>T p.P653S (on ENST00000295566 / NM_139118.2; = p.P596S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs373373657; called by muse, mutect2, varscan2
- ZBBX | c.1850A>G p.N617S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767271017, COSV100284050; called by muse, mutect2
- ZNF148 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100642098; called by muse, mutect2, varscan2
- ZNF510 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99793864; called by muse, mutect2, varscan2
- ZNF518B | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs867823755, COSV100456716; called by muse, mutect2, varscan2
- ZNF800 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV99757924; called by muse, mutect2, varscan2
- ZP4 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100850684; called by muse, mutect2, varscan2
- ZSCAN18 | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV53732346, COSV99559460; called by muse, mutect2
- GABRP | c.1020+2_1020+14del p.X340_splice | Splice Site (DEL) | VAF 10/80 reads (13%) | called by mutect2, pindel, varscan2
- JAKMIP1 | c.1408del p.T470Rfs*22 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, varscan2
- KCNN3 | c.1027del p.Q343Sfs*4 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- SPDYE5 | c.1202T>G p.L401R | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSPO2 | c.131_147del p.K44Tfs*121 | Frame Shift Del (DEL) | VAF 14/154 reads (9%) | called by mutect2, pindel
- ABCA2 | c.4215G>T p.S1405= (on ENST00000614293; = p.S1375= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV55804615, COSV99687672; called by muse, mutect2, varscan2
- ADAMTS20 | c.309C>A p.G103= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV101239351; called by muse, mutect2, varscan2
- ANKRD17 | c.417G>A p.Q139= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100429234; called by muse, mutect2, varscan2
- CEACAM8 | c.723C>A p.T241= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as COSV99747608; called by muse, mutect2, varscan2
- CHMP1B | c.420G>T p.T140= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV52328984, COSV99303583; called by muse, mutect2
- CLEC1B | c.378T>C p.S126= | Silent (SNP) | VAF 48/134 reads (36%) | catalogued as COSV100046073; called by muse, mutect2, varscan2
- CSGALNACT1 | c.252G>A p.E84= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs189893586, COSV59985510; called by muse, mutect2, varscan2
- DYNC2H1 | c.9192A>G p.E3064= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100518623; called by muse, mutect2, varscan2
- EPHA10 | c.1599C>T p.S533= | Silent (SNP) | VAF 50/163 reads (31%) | catalogued as COSV100361301; called by muse, mutect2, varscan2
- FGB | c.828T>C p.N276= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs771496034, COSV100122442; called by muse, mutect2, varscan2
- FLNC | c.5388G>A p.G1796= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV57964326; called by muse, mutect2, varscan2
- FOXB1 | c.147C>T p.Y49= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV101249823; called by muse, mutect2, varscan2
- GPR37 | c.486C>T p.S162= | Silent (SNP) | VAF 13/189 reads (7%) | catalogued as COSV100390823; called by muse, mutect2
- GRAMD1A | c.1269G>T p.L423= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV100526178; called by muse, mutect2, varscan2
- KRTAP10-10 | c.687C>T p.L229= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as rs782180238, COSV59957727; called by muse, mutect2, varscan2
- LRG1 | c.519G>T p.G173= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as COSV100014854, COSV56704286; called by muse, mutect2, varscan2
- LRRTM4 | c.1399C>A p.R467= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV101297568, COSV69139331, COSV69140717; called by muse, mutect2, varscan2
- MYO18B | c.6345C>T p.S2115= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV100123720; called by muse, mutect2, varscan2
- MYO18B | c.6531C>T p.A2177= | Silent (SNP) | VAF 50/231 reads (22%) | catalogued as COSV100123722; called by muse, mutect2, varscan2
- OR4M1 | c.732C>A p.S244= | Silent (SNP) | VAF 29/198 reads (15%) | catalogued as COSV100271213; called by muse, mutect2, varscan2
- OSBPL6 | c.2361G>A p.G787= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs568646326, COSV99507492; called by muse, mutect2, varscan2
- PCDHA4 | c.1086C>T p.D362= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs782725111, COSV63539787; called by muse, mutect2, varscan2
- PCDHB14 | c.2010C>T p.Y670= | Silent (SNP) | VAF 36/257 reads (14%) | catalogued as COSV99505942; called by muse, mutect2, varscan2
- PCDHB3 | c.1905G>T p.A635= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs13179024, COSV50565364, COSV99166562; called by muse, mutect2, varscan2
- PIK3CA | c.2628A>T p.T876= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99837817; called by muse, mutect2, varscan2
- PIP | c.129C>A p.P43= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99344146; called by muse, mutect2, varscan2
- PLEKHA4 | c.1932G>A p.Q644= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99612588; called by muse, mutect2, varscan2
- RBMS3 | c.522C>T p.D174= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs566851242, COSV56160161; called by muse, mutect2, varscan2
- RHCE | c.132C>T p.L44= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs768223782, COSV99604050; called by muse, mutect2, varscan2
- RICTOR | c.1857G>A p.G619= | Silent (SNP) | VAF 57/145 reads (39%) | catalogued as rs762080055, COSV99704962; called by muse, mutect2, varscan2
- SERINC3 | c.1096C>T p.L366= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as COSV99667737; called by muse, mutect2, varscan2
- SLC39A4 | c.1320C>T p.S440= (on ENST00000301305 / NM_001374839.1; = p.S415= on NM_017767.3) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs782193932, COSV99433372; called by muse, mutect2
- STXBP5 | c.2973G>C p.R991= (on ENST00000321680 / NM_001127715.2; = p.R955= on NM_139244.4) | Silent (SNP) | VAF 71/219 reads (32%) | catalogued as COSV51652986, COSV99470289; called by muse, mutect2, varscan2
- TMF1 | c.2763C>T p.R921= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV68375168; called by muse, mutect2, varscan2
- ZNF639 | c.159T>C p.F53= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as COSV100418430; called by muse, mutect2, varscan2
- ZP4 | c.75A>C p.A25= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100850685; called by muse, mutect2, varscan2
- NXF5 | n.1360G>A | RNA (SNP) | VAF 68/113 reads (60%) | catalogued as COSV53790675, COSV99534399; called by muse, mutect2, varscan2
- SNORD115-26 | n.82del | RNA (DEL) | VAF 99/403 reads (25%) | called by mutect2, pindel, varscan2
- SSPOP | n.8502G>T | RNA (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100947434; called by muse, mutect2, varscan2
- TTN | c.10361-5119T>A | Intron (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100613886; called by muse, mutect2
